Somatic mutation profile of cancer-model specimen HCM-SANG-0270-C20-85A (3D Organoid; aliquot HCM-SANG-0270-C20-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-SANG-0270-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-0270-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 100bef86-84c9-4166-a704-cbe7b0ef7cf7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0270-C20-10B (Blood Derived Normal), aliquot HCM-SANG-0270-C20-10B-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec1a1e3d-c0b3-473b-a608-488aa4b208c8

The open-access MAF lists 175 somatic variants for this specimen: 136 protein-altering or splice-affecting, 32 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 130, Silent 32, Intron 4, Nonsense Mutation 2, Frame Shift Del 2, Frame Shift Ins 1, 5'UTR 1, Splice Site 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 315/319 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 102/214 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 287/290 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80338963, CD147870, CM040450, CM041789, CM981228, COSV61683972, COSV61685418, COSV61686083; ClinVar: likely pathogenic / not provided / pathogenic; called by muse, mutect2, varscan2
- ABHD12B | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 168/330 reads (51%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs1392372319; called by muse, mutect2, varscan2
- ACACA | c.1705C>T p.R569C | Missense Mutation (SNP) | VAF 133/335 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs145246486; called by muse, mutect2, varscan2
- ACACB | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 162/318 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs773666938, COSV58131696; called by muse, mutect2, varscan2
- ACADL | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 96/225 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.46); catalogued as rs546101555; called by muse, mutect2, varscan2
- ADAM29 | c.1728C>A p.F576L | Missense Mutation (SNP) | VAF 155/339 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.096); catalogued as COSV100822047; called by muse, mutect2, varscan2
- AHNAK2 | c.13366G>A p.V4456M | Missense Mutation (SNP) | VAF 21/413 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as rs569348872, COSV60926415; called by muse, mutect2
- ANHX | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 112/249 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as rs1480651088, COSV101376525; called by muse, mutect2, varscan2
- APCDD1 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 257/483 reads (53%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.479); catalogued as rs201834801; called by muse, mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 139/318 reads (44%) | catalogued as rs758608743; called by mutect2, varscan2
- ATG2A | c.5656G>A p.V1886M | Missense Mutation (SNP) | VAF 224/500 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765776372; called by muse, mutect2, varscan2
- AZI2 | c.1052T>C p.F351S | Missense Mutation (SNP) | VAF 138/270 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs1354201699; called by muse, mutect2, varscan2
- BCL11A | c.1498G>A p.V500M (on ENST00000335712 / NM_001365609.1; = p.V534M on NM_018014.4) | Missense Mutation (SNP) | VAF 255/529 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.106); catalogued as rs773235162, COSV100186570; called by muse, mutect2, varscan2
- BOP1 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 582/868 reads (67%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs1383645232; called by muse, mutect2, varscan2
- C2orf42 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 98/229 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1388504707; called by muse, mutect2, varscan2
- CEP164 | c.4174C>T p.R1392W | Missense Mutation (SNP) | VAF 66/138 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769676851, COSV99632450; called by muse, mutect2, varscan2
- CHD4 | c.2831G>A p.R944Q (on ENST00000357008 / NM_001363606.2; = p.R957Q on NM_001273.5) | Missense Mutation (SNP) | VAF 183/361 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs76359472, COSV104399234, COSV58904513; called by muse, mutect2, varscan2
- CHMP1A | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 115/254 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.335); catalogued as rs200323717; called by muse, mutect2, varscan2
- DACT2 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 218/403 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748077283; called by muse, mutect2, varscan2
- F13B | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 115/237 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66376011; called by muse, mutect2, varscan2
- FST | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 293/293 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs1177495235; called by muse, mutect2, varscan2
- GABRD | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 156/522 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs749014692; called by muse, mutect2, varscan2
- GLB1L3 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs989291395, COSV66282446; called by muse, mutect2
- GRIK1 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 121/312 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs373016584; called by muse, mutect2, varscan2
- H2BC1 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 179/309 reads (58%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.931); catalogued as rs1351937593, COSV51236761; called by muse, mutect2, varscan2
- HEXIM2 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 173/348 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as rs1267872165; called by muse, mutect2, varscan2
- ILDR2 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 186/367 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs937233990, COSV54833776; called by muse, mutect2, varscan2
- INA | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 29/507 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as COSV100878574; called by muse, mutect2
- ITIH5 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 231/347 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs759497987, COSV56909484; called by muse, mutect2, varscan2
- KCNT1 | c.1366G>A p.A456T (on ENST00000488444; = p.A475T on NM_020822.3) | Missense Mutation (SNP) | VAF 137/491 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as rs144956052; called by muse, mutect2, varscan2
- KIF23 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 85/201 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as rs756964640, COSV52980273; called by muse, mutect2, varscan2
- LAMA4 | c.1447G>T p.A483S (on ENST00000230538 / NM_001105206.3; = p.A476S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/314 reads (37%) | SIFT tolerated (0.84); PolyPhen benign (0.096); catalogued as COSV57903863; called by muse, mutect2, varscan2
- LRRC49 | c.251C>G p.S84C | Missense Mutation (SNP) | VAF 88/207 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as rs150271201; called by muse, mutect2, varscan2
- MAGI2 | c.2671G>A p.A891T | Missense Mutation (SNP) | VAF 87/438 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1052002858, COSV62641530; called by muse, mutect2, varscan2
- MCM10 | c.154G>A p.G52S | Missense Mutation (SNP) | VAF 153/456 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.152); catalogued as rs753259372, COSV66333608; called by muse, mutect2, varscan2
- MYBPC3 | c.3277G>A p.G1093S | Missense Mutation (SNP) | VAF 177/368 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs727503173; called by muse, mutect2, varscan2
- NLGN4X | c.2103C>A p.D701E | Missense Mutation (SNP) | VAF 56/375 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.751); catalogued as COSV99320586; called by muse, mutect2, varscan2
- NLRP4 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 154/330 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.307); catalogued as rs772979970; called by muse, mutect2, varscan2
- NOTCH2 | c.5105G>A p.R1702Q | Missense Mutation (SNP) | VAF 102/228 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs999822357, COSV56709641; called by muse, mutect2, varscan2
- NOTCH4 | c.2401C>T p.R801C | Missense Mutation (SNP) | VAF 20/478 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.828); catalogued as rs369297005; called by muse, mutect2
- NRXN1 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 140/279 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372823663; called by muse, mutect2, varscan2
- NTRK3 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 209/414 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as rs183806623, COSV100448367, COSV58112677, COSV58116202; called by muse, mutect2, varscan2
- NUP160 | c.3719C>T p.T1240M | Missense Mutation (SNP) | VAF 103/225 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs535059681, COSV65854418; called by muse, mutect2, varscan2
- OR4N2 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 179/739 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs201108157, COSV60050074; called by muse, mutect2, varscan2
- OR51E2 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 132/315 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.081); catalogued as rs142195646, COSV101211306; called by muse, mutect2, varscan2
- OR52N1 | c.455T>G p.L152R | Missense Mutation (SNP) | VAF 13/364 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV57693950, COSV57693989; called by muse, mutect2
- OR5J2 | c.429G>T p.E143D | Missense Mutation (SNP) | VAF 155/321 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV56623841; called by muse, mutect2, varscan2
- PKHD1L1 | c.7336C>T p.P2446S | Missense Mutation (SNP) | VAF 110/360 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs1343952887; called by muse, mutect2, varscan2
- PQBP1 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 168/402 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.207); catalogued as rs782506693; called by muse, mutect2, varscan2
- PRM1 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 131/278 reads (47%) | PolyPhen probably damaging (0.928); catalogued as rs374230515; called by muse, mutect2, varscan2
- SERPINF1 | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 155/355 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs376520683; called by muse, mutect2, varscan2
- SIGLEC12 | c.1447G>A p.G483R (on ENST00000291707 / NM_053003.4; = p.G365R on NM_033329.2) | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.344); catalogued as rs372236004; called by muse, mutect2, varscan2
- SNAPC2 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 214/434 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.699); catalogued as rs1009937630, COSV55604301; called by muse, mutect2, varscan2
- SRSF7 | c.381A>C p.R127S | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs148174608; called by muse, mutect2, varscan2
- TMEM225 | c.118G>T p.D40Y | Missense Mutation (SNP) | VAF 154/348 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.578); catalogued as COSV66693732; called by muse, mutect2, varscan2
- TRPA1 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 44/405 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.288); catalogued as COSV51555755; called by muse, mutect2, varscan2
- ANK2 | c.8589A>C p.E2863D | Missense Mutation (SNP) | VAF 15/266 reads (6%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2
- ANO4 | c.1078A>T p.M360L (on ENST00000392977 / NM_001286615.2; = p.M325L on NM_178826.4) | Missense Mutation (SNP) | VAF 152/317 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- ANTXR1 | c.1472A>G p.Q491R | Missense Mutation (SNP) | VAF 22/526 reads (4%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2
- BRD1 | c.128A>T p.E43V | Missense Mutation (SNP) | VAF 10/330 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2
- C19orf54 | c.546G>T p.E182D | Missense Mutation (SNP) | VAF 18/353 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.301); called by muse, mutect2
- CARD8 | c.1478A>G p.K493R (on ENST00000651546 / NM_001184900.3; = p.K443R on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/476 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.258); called by muse, mutect2
- CTNNB1 | c.533T>G p.L178R | Missense Mutation (SNP) | VAF 176/178 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP1B1 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 244/473 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- DCLK1 | c.557A>T p.K186M | Missense Mutation (SNP) | VAF 108/341 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DNAH9 | c.6368A>C p.K2123T | Missense Mutation (SNP) | VAF 9/262 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2
- FAM168B | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 26/384 reads (7%) | called by muse, mutect2
- FAM181A | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 18/390 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2
- FAT2 | c.971A>T p.E324V | Missense Mutation (SNP) | VAF 12/398 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.054); called by muse, mutect2
- FBXO40 | c.1643A>G p.E548G | Missense Mutation (SNP) | VAF 24/396 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- FBXO46 | c.1604A>C p.K535T | Missense Mutation (SNP) | VAF 24/456 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- FIZ1 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 244/498 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- FLT1 | c.1279A>G p.K427E | Missense Mutation (SNP) | VAF 10/289 reads (3%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.872); called by muse, mutect2
- FOXJ1 | c.851A>T p.K284M | Missense Mutation (SNP) | VAF 27/566 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2
- GALNT9 | c.1337A>G p.K446R (on ENST00000328957 / NM_001122636.2; = p.K80R on NM_021808.3) | Missense Mutation (SNP) | VAF 15/408 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2
- GLI3 | c.1529A>C p.K510T | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); called by muse, mutect2
- GLTP | c.302T>G p.L101R | Missense Mutation (SNP) | VAF 11/233 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GOLGB1 | c.4342A>G p.K1448E | Missense Mutation (SNP) | VAF 15/383 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.122); called by muse, mutect2
- GPRASP2 | c.1442A>G p.E481G | Missense Mutation (SNP) | VAF 12/358 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2
- GSDMC | c.570+1G>C p.X190_splice | Splice Site (SNP) | VAF 181/265 reads (68%) | called by muse, mutect2, varscan2
- HS3ST5 | c.611A>G p.N204S | Missense Mutation (SNP) | VAF 216/363 reads (60%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- JARID2 | c.1519A>C p.S507R | Missense Mutation (SNP) | VAF 16/487 reads (3%) | SIFT tolerated (0.57); PolyPhen benign (0.015); called by muse, mutect2
- KCNH7 | c.202T>G p.F68V | Missense Mutation (SNP) | VAF 26/412 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIAA1671 | c.4099C>T p.P1367S | Missense Mutation (SNP) | VAF 26/422 reads (6%) | SIFT tolerated (0.83); PolyPhen benign (0.013); called by muse, mutect2
- L1CAM | c.1183C>A p.Q395K | Missense Mutation (SNP) | VAF 31/632 reads (5%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.515); called by muse, mutect2
- LRP1B | c.5543T>C p.L1848P | Missense Mutation (SNP) | VAF 10/296 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MTHFD1L | c.2919A>C p.Q973H | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2
- MTHFR | c.1388A>T p.E463V | Missense Mutation (SNP) | VAF 14/375 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MUC16 | c.29665A>G p.T9889A | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2
- MUC16 | c.10645T>G p.S3549A | Missense Mutation (SNP) | VAF 18/472 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2
- MYH14 | c.1444T>G p.F482V | Missense Mutation (SNP) | VAF 15/348 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NDRG1 | c.1030T>G p.S344A | Missense Mutation (SNP) | VAF 30/1020 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.174); called by muse, mutect2
- NEFH | c.1151A>C p.E384A | Missense Mutation (SNP) | VAF 16/303 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- NFIB | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 192/303 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NHS | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 278/530 reads (52%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLRP2 | c.2429A>C p.N810T | Missense Mutation (SNP) | VAF 26/568 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- PCDH17 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 153/484 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- PCDHB4 | c.901C>A p.L301M | Missense Mutation (SNP) | VAF 69/166 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- PDILT | c.1253A>T p.K418I | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.458); called by muse, mutect2
- PIK3R1 | c.460_461del p.S154Lfs*12 | Frame Shift Del (DEL) | VAF 215/345 reads (62%) | called by pindel, varscan2
- PP2D1 | c.839A>C p.E280A | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- RBSN | c.1316A>C p.K439T | Missense Mutation (SNP) | VAF 15/460 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); called by muse, mutect2
- ROS1 | c.3653T>C p.F1218S | Missense Mutation (SNP) | VAF 71/174 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- RPL5 | c.883G>C p.A295P | Missense Mutation (SNP) | VAF 84/181 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- RPP25L | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 410/595 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- RRAGD | c.962T>G p.L321R | Missense Mutation (SNP) | VAF 15/407 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2
- RTF1 | c.922A>C p.T308P | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2
- SAMD15 | c.1610A>C p.E537A | Missense Mutation (SNP) | VAF 13/342 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.037); called by muse, mutect2
- SEMA5B | c.2390G>A p.R797Q | Missense Mutation (SNP) | VAF 266/540 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SIK2 | c.1408T>A p.F470I | Missense Mutation (SNP) | VAF 12/330 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.085); called by muse, mutect2
- SLC15A3 | c.366_372del p.F123Tfs*63 | Frame Shift Del (DEL) | VAF 225/484 reads (46%) | called by mutect2, pindel, varscan2
- SLC22A25 | c.1365A>C p.Q455H | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- SLC6A15 | c.1004T>A p.V335D | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2
- SUPT5H | c.1414T>G p.F472V | Missense Mutation (SNP) | VAF 19/304 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- SUV39H1 | c.541T>C p.C181R | Missense Mutation (SNP) | VAF 20/567 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SYNE1 | c.22830A>C p.K7610N (on ENST00000367255 / NM_182961.4; = p.K7539N on NM_033071.3) | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- SYNE1 | c.5848G>T p.A1950S (on ENST00000367255 / NM_182961.4; = p.A1957S on NM_033071.3) | Missense Mutation (SNP) | VAF 104/376 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TESC | c.559T>G p.F187V | Missense Mutation (SNP) | VAF 17/231 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TMEM132C | c.2648G>A p.G883E | Missense Mutation (SNP) | VAF 24/469 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2
- TNR | c.2191A>G p.T731A | Missense Mutation (SNP) | VAF 20/394 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.713); called by muse, mutect2
- TRAV19 | c.227A>C p.E76A | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.476); called by muse, mutect2
- TRPM1 | c.1782A>C p.E594D | Missense Mutation (SNP) | VAF 20/546 reads (4%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.497); called by muse, mutect2
- TTN | c.805C>G p.P269A | Missense Mutation (SNP) | VAF 11/302 reads (4%) | PolyPhen benign (0.352); called by muse, mutect2
- TUBGCP4 | c.1361G>A p.G454D (on ENST00000260383 / NM_001286414.3; = p.G453D on NM_014444.5) | Missense Mutation (SNP) | VAF 12/323 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.039); called by muse, mutect2
- TXNIP | c.683A>C p.K228T | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.127); called by muse, mutect2
- UBE2L3 | c.113T>A p.L38H | Missense Mutation (SNP) | VAF 9/303 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- UBE4B | c.1054A>G p.S352G | Missense Mutation (SNP) | VAF 25/622 reads (4%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2
- UBR4 | c.9059C>G p.A3020G | Missense Mutation (SNP) | VAF 112/259 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- USP17L1 | c.1323A>C p.Q441H | Missense Mutation (SNP) | VAF 28/736 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZBTB7B | c.1163A>C p.K388T (on ENST00000292176; = p.K422T on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 109/230 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF549 | c.1561A>T p.R521* (on ENST00000376233 / NM_001199295.2; = p.R508* on NM_153263.2) | Nonsense Mutation (SNP) | VAF 14/281 reads (5%) | called by muse, mutect2
- ZNF680 | c.1264A>C p.T422P | Missense Mutation (SNP) | VAF 11/335 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2
- ZNF799 | c.1477C>G p.Q493E | Missense Mutation (SNP) | VAF 79/206 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF836 | c.2750T>G p.L917R | Missense Mutation (SNP) | VAF 17/213 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.22); called by muse, mutect2
- ADCY8 | c.489T>G p.S163= | Silent (SNP) | VAF 16/614 reads (3%) | called by muse, mutect2
- AGL | c.1656A>G p.V552= | Silent (SNP) | VAF 111/246 reads (45%) | called by muse, mutect2, varscan2
- ALMS1 | c.1056A>G p.K352= | Silent (SNP) | VAF 13/251 reads (5%) | called by muse, mutect2
- AMER1 | c.1047G>A p.Q349= | Silent (SNP) | VAF 28/584 reads (5%) | called by muse, mutect2
- AVPR1A | c.36G>A p.S12= | Silent (SNP) | VAF 79/275 reads (29%) | catalogued as rs1414515126, COSV54547254; called by muse, mutect2, varscan2
- BRCA2 | c.4305T>C p.N1435= | Silent (SNP) | VAF 12/342 reads (4%) | catalogued as rs878853583; called by muse, mutect2
- CACNA1E | c.2433C>A p.L811= | Silent (SNP) | VAF 206/496 reads (42%) | called by muse, mutect2, varscan2
- CCSER1 | c.2316G>A p.A772= | Silent (SNP) | VAF 148/284 reads (52%) | catalogued as rs1397732187; called by muse, mutect2, varscan2
- DEGS1 | c.375G>A p.K125= | Silent (SNP) | VAF 15/366 reads (4%) | called by muse, mutect2
- GABPA | c.27G>A p.L9= | Silent (SNP) | VAF 16/268 reads (6%) | called by muse, mutect2
- GJC2 | c.531G>A p.A177= | Silent (SNP) | VAF 266/516 reads (52%) | catalogued as rs776968941; called by muse, varscan2
- HERC1 | c.8082T>C p.L2694= | Silent (SNP) | VAF 115/233 reads (49%) | called by muse, mutect2, varscan2
- KIAA1549L | c.4641C>T p.I1547= (on ENST00000321505; = p.I1844= on NM_012194.3) | Silent (SNP) | VAF 132/301 reads (44%) | catalogued as rs368722488; called by muse, varscan2
- KRTAP12-3 | c.141T>G p.A47= | Silent (SNP) | VAF 19/646 reads (3%) | called by muse, mutect2
- LSR | c.1845C>T p.Y615= (on ENST00000361790; = p.Y596= on NM_015925.6) | Silent (SNP) | VAF 184/408 reads (45%) | called by muse, mutect2, varscan2
- NYAP2 | c.993T>C p.S331= | Silent (SNP) | VAF 11/314 reads (4%) | called by muse, mutect2
- PASK | c.2403C>T p.T801= | Silent (SNP) | VAF 173/345 reads (50%) | catalogued as rs568061248, COSV52153621; called by muse, mutect2, varscan2
- RYR2 | c.3180C>T p.Y1060= | Silent (SNP) | VAF 34/281 reads (12%) | catalogued as rs398123540, COSV63721277; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- SHANK3 | c.4077C>T p.S1359= | Silent (SNP) | VAF 218/441 reads (49%) | catalogued as rs754778424; called by muse, mutect2, varscan2
- SHCBP1L | c.384C>T p.D128= | Silent (SNP) | VAF 151/291 reads (52%) | catalogued as COSV100840934; called by muse, mutect2, varscan2
- SIPA1 | c.105G>A p.P35= | Silent (SNP) | VAF 283/567 reads (50%) | catalogued as rs768841771; called by muse, mutect2, varscan2
- SIT1 | c.435C>T p.P145= | Silent (SNP) | VAF 34/742 reads (5%) | catalogued as rs138376414, COSV52399632; ClinVar: likely benign; called by muse, mutect2
- SLITRK2 | c.912G>A p.P304= | Silent (SNP) | VAF 190/417 reads (46%) | catalogued as rs377471915; called by muse, mutect2, varscan2
- SOX11 | c.426G>A p.A142= | Silent (SNP) | VAF 154/304 reads (51%) | catalogued as rs1435669765; called by mutect2, varscan2
- SPIDR | c.669G>C p.L223= | Silent (SNP) | VAF 112/399 reads (28%) | called by muse, mutect2, varscan2
- SRGAP3 | c.2208G>A p.E736= | Silent (SNP) | VAF 244/248 reads (98%) | called by muse, mutect2, varscan2
- SYN2 | c.72C>T p.T24= | Silent (SNP) | VAF 12/311 reads (4%) | catalogued as rs1486128095; called by muse, mutect2
- TDRD9 | c.447C>T p.S149= | Silent (SNP) | VAF 105/198 reads (53%) | catalogued as COSV59142753; called by muse, mutect2, varscan2
- TGFBRAP1 | c.636C>T p.I212= | Silent (SNP) | VAF 149/282 reads (53%) | catalogued as rs772448911, COSV51515853; called by muse, mutect2, varscan2
- USP34 | c.7947G>A p.Q2649= | Silent (SNP) | VAF 100/283 reads (35%) | called by muse, mutect2, varscan2
- WDFY3 | c.4180A>C p.R1394= | Silent (SNP) | VAF 7/173 reads (4%) | called by muse, mutect2
- ZNF331 | c.1218C>A p.T406= | Silent (SNP) | VAF 103/216 reads (48%) | catalogued as rs764501728; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73847770 C>T | 5'Flank (SNP) | VAF 8/207 reads (4%) | called by muse, mutect2
- DEPDC5 | c.2120+126G>A | Intron (SNP) | VAF 69/158 reads (44%) | called by muse, mutect2, varscan2
- FBXL22 | c.354-562G>A | Intron (SNP) | VAF 172/370 reads (46%) | catalogued as rs1425407045; called by muse, mutect2, varscan2
- MGAM | c.4619-2014C>T | Intron (SNP) | VAF 100/365 reads (27%) | catalogued as rs754337224; called by muse, mutect2, varscan2
- OSGIN1 | n.2012C>T | RNA (SNP) | VAF 175/393 reads (45%) | catalogued as rs536349060, COSV59423909; called by muse, mutect2, varscan2
- TFEC | c.-55A>T | 5'UTR (SNP) | VAF 125/375 reads (33%) | called by muse, mutect2, varscan2
- UNC13B | c.762-4654dup | Intron (INS) | VAF 195/403 reads (48%) | called by mutect2, pindel, varscan2
